Somatic mutation profile of tumor specimen TCGA-QB-A6FS-06A (aliquot TCGA-QB-A6FS-06A-11D-A30X-08) from TCGA case TCGA-QB-A6FS, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 49.7 years (18,161 days).
Specimen TCGA-QB-A6FS-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb2b9198-cba4-4f90-9950-a0f8258e10e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QB-A6FS-10A (Blood Derived Normal), aliquot TCGA-QB-A6FS-10A-01D-A30X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a63b0948-9c8b-40c5-9480-e00c073756f3

The open-access MAF lists 1,401 somatic variants for this specimen: 917 protein-altering or splice-affecting, 450 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 839, Silent 450, Nonsense Mutation 55, Intron 17, Splice Region 14, RNA 8, Splice Site 7, 5'Flank 5, 3'UTR 2, 5'UTR 2, Frame Shift Del 1, In Frame Del 1.

Variants (750 of 1,401; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.5606C>T p.P1869L | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs376925793; ClinVar: likely pathogenic; called by muse, varscan2
- ABCC6 | c.3507-1G>A p.X1169_splice | Splice Site (SNP) | VAF 10/42 reads (24%) | catalogued as rs72664210, CS053440, COSV52745796; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ASXL2 | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 31/131 reads (24%) | hotspot (GDC flag); catalogued as COSV55455231; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/118 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 70/123 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- HSD11B1 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs387907168, CM111740, COSV54828579; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NEXN | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.775); catalogued as rs971313210, COSV57358805; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RAC1 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 26/61 reads (43%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); catalogued as rs1057519948, COSV61821585, COSV61824963; ClinVar: likely pathogenic; called by muse, mutect2
- A1CF | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as COSV50957343, COSV51028098; called by muse, mutect2, varscan2
- AACS | c.1999C>T p.P667S | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.922); catalogued as COSV99908227; called by muse, mutect2, varscan2
- AACS | c.2000C>T p.P667L | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99908228; called by muse, mutect2, varscan2
- ABCA5 | c.3641C>T p.P1214L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV67017822; called by muse, mutect2
- ABCB4 | c.2314C>T p.Q772* | Nonsense Mutation (SNP) | VAF 13/29 reads (45%) | catalogued as COSV55938193; called by muse, mutect2
- ABCB5 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV68855151; called by muse, mutect2, varscan2
- ABCC3 | c.3862G>A p.E1288K | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs1292934429, COSV53325327; called by muse, mutect2, varscan2
- ABCD2 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV58051835; called by muse, mutect2, varscan2
- ABCE1 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56847888; called by muse, mutect2, varscan2
- AC098582.1 | c.1084C>T p.H362Y | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52022340; called by muse, mutect2
- ACAD9 | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.86); PolyPhen benign (0.012); catalogued as rs1435779305, COSV58308724; called by muse, mutect2, varscan2
- ACAN | c.6152C>T p.S2051F | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.103); catalogued as COSV61361786; called by muse, mutect2, varscan2
- ACAN | c.6304G>A p.E2102K | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV61364404; called by muse, mutect2, varscan2
- ACMSD | c.573G>A p.W191* | Nonsense Mutation (SNP) | VAF 28/118 reads (24%) | catalogued as COSV51606519; called by muse, varscan2
- ACO1 | c.1622G>A p.R541Q | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752397721, COSV59381802; called by muse, mutect2, varscan2
- ACSM2A | c.523C>T p.P175S (on ENST00000219054; = p.P96S on NM_001308169.2) | Missense Mutation (SNP) | VAF 44/192 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.156); catalogued as rs746564717, COSV54586985; called by mutect2, varscan2
- ACSM2B | c.1073G>A p.R358Q | Missense Mutation (SNP) | VAF 59/228 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.277); catalogued as rs374731787; called by muse, mutect2, varscan2
- ACSS3 | c.531G>A p.M177I | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54085309, COSV54093705; called by muse, mutect2, varscan2
- ACTRT1 | c.971A>G p.K324R | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as COSV64419731; called by muse, mutect2, varscan2
- ACVR2A | c.1339A>T p.K447* | Nonsense Mutation (SNP) | VAF 18/88 reads (20%) | catalogued as COSV54025585; called by muse, mutect2, varscan2
- ADAM23 | c.851G>A p.R284K | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV52221298; called by muse, mutect2, varscan2
- ADAMTS15 | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54507705; called by muse, mutect2, varscan2
- ADAMTS18 | c.1628C>T p.S543L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV51419022; called by muse, mutect2, varscan2
- ADAMTS6 | c.731G>A p.R244K | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as rs1029123862, COSV66861957; called by muse, mutect2, varscan2
- ADAMTSL1 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.859); catalogued as COSV52819643; called by muse, mutect2, varscan2
- ADAMTSL4 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 23/214 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as COSV55003211; called by muse, mutect2, varscan2
- ADCY1 | c.1456C>T p.P486S | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.054); catalogued as COSV52036628; called by muse, mutect2, varscan2
- ADCY1 | c.1624G>A p.A542T | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV52034664, COSV52038244; called by muse, mutect2, varscan2
- ADGRV1 | c.5401G>A p.E1801K | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV67989879; called by muse, mutect2
- ADH7 | c.641G>A p.G214E | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52921999; called by muse, mutect2, varscan2
- ADIPOQ | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.034); catalogued as rs762671089, COSV57859536; called by muse, mutect2, varscan2
- AFF3 | c.3365C>T p.P1122L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.54); PolyPhen probably damaging (1); catalogued as COSV57861868; called by muse, mutect2, varscan2
- AFP | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.589); catalogued as rs896537897, COSV56926019; called by muse, varscan2
- AGTPBP1 | c.1424T>C p.V475A (on ENST00000357081 / NM_001330701.2; = p.V435A on NM_015239.2) | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV61274362; called by muse, mutect2, varscan2
- AJAP1 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65452005; called by muse, mutect2, varscan2
- AK4 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs1214953582, COSV59198354; called by muse, mutect2, varscan2
- AL645922.1 | c.3046G>A p.A1016T | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.047); catalogued as rs1388436433, COSV54961504; called by muse, mutect2, varscan2
- ALPI | c.1355G>A p.G452E | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55015311; called by muse, mutect2
- AMIGO2 | c.521G>A p.G174E | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.119); catalogued as COSV56974882; called by muse, mutect2, varscan2
- ANK3 | c.7444G>A p.E2482K | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.551); catalogued as rs865775713, COSV55045002, COSV55068487; called by muse, mutect2, varscan2
- ANKFN1 | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV59452959; called by muse, mutect2, varscan2
- ANKRD26 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV65796349; called by muse, mutect2, varscan2
- ANKS1B | c.2162C>T p.S721L | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs771865396, COSV61361867; called by muse, mutect2, varscan2
- ANKS1B | c.564G>A p.M188I | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.374); catalogued as COSV61361874; called by muse, mutect2, varscan2
- ANO4 | c.886C>T p.P296S (on ENST00000392977 / NM_001286615.2; = p.P261S on NM_178826.4) | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54603900; called by muse, mutect2, varscan2
- ANO7 | c.716+1G>A p.X239_splice (on ENST00000274979; = p.X185_splice on NM_001370694.2) | Splice Site (SNP) | VAF 7/38 reads (18%) | catalogued as COSV51474744; called by muse, mutect2, varscan2
- AOC1 | c.1081G>A p.G361R | Missense Mutation (SNP) | VAF 48/190 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV62869771; called by muse, mutect2, varscan2
- APOBEC3G | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.751); catalogued as COSV101349106; called by muse, mutect2, varscan2
- APOM | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV99277465; called by muse, mutect2, varscan2
- AQP2 | c.472G>A p.G158S | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1382728989, COSV52231032; called by muse, mutect2
- AREG | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.52); catalogued as rs1439656918, COSV52644968; called by muse, mutect2, varscan2
- ARFGEF3 | c.4900G>A p.E1634K | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs1156624777, COSV52463055, COSV52470565; called by muse, mutect2, varscan2
- ARFIP1 | c.817G>A p.D273N (on ENST00000353617 / NM_001287432.1; = p.D241N on NM_014447.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61885414; called by muse, mutect2, varscan2
- ARGFX | c.910C>T p.Q304* | Nonsense Mutation (SNP) | VAF 21/77 reads (27%) | catalogued as COSV57682996; called by muse, mutect2, varscan2
- ARHGAP21 | c.3763C>T p.R1255C | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57605752; called by muse, mutect2, varscan2
- ARHGAP22 | c.1841G>A p.R614Q | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.616); catalogued as COSV50957442; called by muse, mutect2
- ARHGEF18 | c.1478C>T p.S493L (on ENST00000359920 / NM_001130955.2; = p.S389L on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs765235100, COSV60468020; called by muse, mutect2, varscan2
- ARHGEF2 | c.1214C>T p.S405F (on ENST00000361247 / NM_001162383.2; = p.S377F on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58113520; called by muse, mutect2, varscan2
- ARMC4 | c.1472G>A p.R491K | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as COSV59467798; called by muse, mutect2, varscan2
- ARSJ | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as COSV59537913; called by muse, mutect2
- ASB10 | c.1034G>A p.S345N (on ENST00000420175 / NM_001142459.2; = p.S330N on NM_080871.4) | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.029); catalogued as COSV51994833, COSV51998394; called by muse, mutect2
- ASB4 | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs267601648, COSV57946501; called by muse, mutect2, varscan2
- ASH1L | c.4760C>T p.S1587F | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV64210523; called by muse, mutect2, varscan2
- ASIC1 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57319005; called by muse, mutect2, varscan2
- ASPH | c.798T>A p.Y266* | Nonsense Mutation (SNP) | VAF 16/51 reads (31%) | catalogued as COSV62860423; called by muse, mutect2, varscan2
- ASTN2 | c.1165C>T p.R389* | Nonsense Mutation (SNP) | VAF 7/41 reads (17%) | catalogued as rs762528231, COSV100524617, COSV100529647; called by muse, mutect2, varscan2
- ASXL1 | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 67/212 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370054224; called by muse, mutect2, varscan2
- ATF2 | c.121C>T p.H41Y | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV51371400; called by muse, mutect2, varscan2
- ATOH8 | c.572C>T p.S191F | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV60401063; called by muse, mutect2
- ATP13A2 | c.1088C>T p.P363L | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV58701992; called by muse, mutect2, varscan2
- ATP1A2 | c.2015C>T p.S672L | Missense Mutation (SNP) | VAF 74/129 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs145701604; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- ATP2B2 | c.799G>A p.G267S | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59502076; called by muse, mutect2, varscan2
- AUTS2 | c.3014C>T p.P1005L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.129); catalogued as rs750470894, COSV61416309; called by muse, mutect2, varscan2
- AXDND1 | c.1286G>A p.G429D | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV62645006; called by muse, mutect2, varscan2
- BARX2 | c.251C>T p.S84F | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.564); catalogued as COSV55651302; called by muse, mutect2, varscan2
- BARX2 | c.337G>A p.G113S | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1432079880, COSV55651309; called by muse, mutect2, varscan2
- BAZ2B | c.5107G>A p.D1703N | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58605106; called by muse, mutect2, varscan2
- BCAN | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 29/217 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61257992; called by muse, mutect2, varscan2
- BCL11B | c.2386G>A p.D796N (on ENST00000357195 / NM_001282237.2; = p.D725N on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61737153; called by muse, mutect2
- BDKRB2 | c.800G>A p.R267K | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60015829; called by muse, mutect2, varscan2
- BEST3 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); catalogued as COSV58303052; called by muse, mutect2, varscan2
- BRPF3 | c.2882C>G p.A961G | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.018); catalogued as COSV60208464; called by muse, mutect2, varscan2
- BTBD16 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.311); catalogued as COSV53264563; called by muse, mutect2, varscan2
- BTG1 | c.446G>T p.C149F | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV99755692; called by muse, mutect2, varscan2
- BTG1 | c.445T>G p.C149G | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.732); catalogued as COSV99755693; called by muse, mutect2, varscan2
- C10orf71 | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.278); catalogued as rs758980501, COSV60509997; called by muse, mutect2, varscan2
- C2orf80 | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV58017740; called by muse, mutect2, varscan2
- C4B | c.3364C>T p.P1122S | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.579); catalogued as COSV70313532; called by muse, mutect2, varscan2
- CACNA1A | c.1992C>T p.I664= | Splice Region (SNP) | VAF 41/164 reads (25%) | catalogued as rs764413479, COSV64204188; ClinVar: likely benign; called by muse, mutect2, varscan2
- CACNA1A | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV64194831; called by muse, mutect2, varscan2
- CACNA1C | c.1342G>A p.D448N | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs786205746, COSV59742852; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1E | c.530G>A p.G177E | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs751409680, COSV62405324; called by muse, mutect2
- CACNA1E | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV62386290; called by muse, mutect2, varscan2
- CACNA1G | c.1957C>T p.P653S | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV61732015; called by muse, mutect2, varscan2
- CACNA1H | c.6986C>T p.P2329L | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs1433357008, COSV52356287; called by muse, mutect2, varscan2
- CACNA1I | c.2677G>A p.E893K | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.971); catalogued as COSV60813453; called by muse, mutect2, varscan2
- CACNA2D1 | c.1988C>T p.P663L (on ENST00000356253 / NM_001366867.1; = p.P651L on NM_000722.4) | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV100667221, COSV62384991; called by muse, mutect2, varscan2
- CACNA2D2 | c.2638G>A p.D880N (on ENST00000479441 / NM_001174051.3; = p.D873N on NM_006030.4) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as COSV56566059; called by muse, mutect2, varscan2
- CACNA2D3 | c.2059G>A p.D687N | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as COSV55558293; called by muse, mutect2, varscan2
- CAD | c.3365C>T p.P1122L | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53029086; called by muse, mutect2, varscan2
- CAMK1D | c.1007C>T p.S336L | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs767783056, COSV66615475; called by muse, mutect2, varscan2
- CAMK2G | c.65+1G>A p.X22_splice | Splice Site (SNP) | VAF 8/30 reads (27%) | catalogued as COSV99990151; called by mutect2, varscan2
- CAMTA1 | c.185C>G p.P62R | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57913062; called by muse, mutect2, varscan2
- CAND2 | c.1564C>T p.L522F (on ENST00000456430 / NM_001162499.2; = p.L429F on NM_012298.3) | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs746186309, COSV55991998; called by muse, mutect2, varscan2
- CAPN15 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.64); PolyPhen benign (0.343); catalogued as rs762068414, COSV99562720; called by muse, varscan2
- CAPZA3 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs769365098, COSV56850079; called by muse, mutect2, varscan2
- CASR | c.287G>A p.R96K | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.012); catalogued as COSV56139230; called by muse, mutect2, varscan2
- CASZ1 | c.157C>T p.H53Y | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.037); catalogued as COSV59738424; called by muse, mutect2
- CATSPERD | c.679C>T p.H227Y | Missense Mutation (SNP) | VAF 68/285 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.111); catalogued as COSV67535788; called by muse, mutect2, varscan2
- CBLB | c.1363C>T p.R455C | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs781633028, COSV51431172; called by muse, mutect2, varscan2
- CBLIF | c.1151C>G p.T384R | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57239681; called by muse, mutect2, varscan2
- CBY2 | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV60118993; called by muse, mutect2
- CC2D2B | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV60358562; called by muse, mutect2, varscan2
- CCAR2 | c.1240G>A p.G414R | Missense Mutation (SNP) | VAF 47/156 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1218201929, COSV52385501; called by muse, mutect2, varscan2
- CCDC39 | c.1788G>A p.M596I | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.116); catalogued as COSV56482286, COSV56488217; called by muse, mutect2, varscan2
- CCDC80 | c.2671G>A p.D891N | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs765977366, COSV52818347; called by muse, mutect2, varscan2
- CCDC88A | c.3044G>A p.R1015K | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV55060559, COSV55065554; called by muse, mutect2, varscan2
- CCNB3 | c.4087C>T p.H1363Y | Missense Mutation (SNP) | VAF 60/136 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV52076476; called by muse, mutect2, varscan2
- CCNI2 | c.749G>A p.G250E | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV66394631; called by muse, mutect2, varscan2
- CCR10 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs747087633, COSV52852284; called by muse, mutect2, varscan2
- CD1D | c.574C>T p.L192F | Missense Mutation (SNP) | VAF 25/349 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); catalogued as rs781320176, COSV63809439; called by muse, mutect2
- CDCA2 | c.2738C>T p.P913L | Missense Mutation (SNP) | VAF 62/217 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1346914882, COSV57944280; called by muse, mutect2, varscan2
- CDCA7L | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as rs781742118, COSV60966276; called by muse, mutect2, varscan2
- CDH10 | c.1657G>A p.G553R | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.808); catalogued as COSV52584569; called by muse, mutect2, varscan2
- CDH12 | c.1282G>A p.G428R | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.102); catalogued as rs1318223202, COSV66423639; called by muse, mutect2, varscan2
- CDH17 | c.2117C>T p.S706F | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.698); catalogued as rs267602042, COSV50326035; called by muse, mutect2, varscan2
- CDH2 | c.2617C>T p.L873F | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52287430; called by muse, mutect2, varscan2
- CDH2 | c.2212C>T p.L738F | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99298062; called by muse, mutect2, varscan2
- CDH23 | c.296C>T p.S99L | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.769); catalogued as COSV54942604; called by muse, mutect2, varscan2
- CDH24 | c.2132C>T p.P711L | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.061); catalogued as rs1271019806, COSV57462175; called by muse, mutect2, varscan2
- CDHR2 | c.1336G>A p.A446T | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV99992052; called by muse, mutect2, varscan2
- CDHR5 | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs1211824413, COSV51564686; called by muse, mutect2, varscan2
- CDKL2 | c.11A>G p.Y4C | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56734254; called by muse, mutect2, varscan2
- CEACAM21 | c.184C>T p.L62F | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as COSV51815117; called by muse, mutect2, varscan2
- CECR2 | c.4102C>T p.P1368S (on ENST00000342247 / NM_001290047.2; = p.P1184S on NM_001290046.1) | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV52844575; called by muse, mutect2, varscan2
- CELSR1 | c.5297G>A p.G1766E | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV53094355, COSV99417556; called by muse, varscan2
- CELSR1 | c.2896C>T p.L966F | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1434430676, COSV53094364; called by muse, mutect2, varscan2
- CELSR2 | c.2236C>T p.R746C | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780995915, COSV54775709; called by muse, mutect2, varscan2
- CEP170 | c.4073T>G p.V1358G | Missense Mutation (SNP) | VAF 61/106 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60511327; called by muse, mutect2, varscan2
- CEP170B | c.3205C>T p.P1069S (on ENST00000453495; = p.P998S on NM_015005.3) | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.121); catalogued as rs1481601916, COSV101371594, COSV69025442; called by muse, mutect2, varscan2
- CEP85 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as COSV53330927; called by muse, mutect2
- CERKL | c.925C>T p.L309F (on ENST00000339098 / NM_001030311.2; = p.L283F on NM_201548.5) | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.532); catalogued as rs1456868672, COSV59208648, COSV59210432; called by muse, mutect2, varscan2
- CFAP251 | c.2671C>T p.P891S | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.927); catalogued as rs1440018892, COSV56612924; called by muse, mutect2, varscan2
- CFAP47 | c.1618C>G p.R540G | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.109); catalogued as COSV52888310; called by muse, mutect2, varscan2
- CFHR2 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66381623; called by muse, mutect2, varscan2
- CFHR2 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.089); catalogued as COSV100804371, COSV66380555; called by muse, mutect2, varscan2
- CHAT | c.1231G>A p.G411R | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746595362, COSV100341012, COSV60328546; called by muse, mutect2, varscan2
- CHD6 | c.2159C>T p.S720F | Missense Mutation (SNP) | VAF 71/203 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58554754; called by muse, mutect2, varscan2
- CHST11 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57990824; called by muse, mutect2, varscan2
- CLEC4M | c.130+1G>A p.X44_splice | Splice Site (SNP) | VAF 19/66 reads (29%) | catalogued as COSV50221549; called by muse, mutect2, varscan2
- CLRN1 | c.602T>A p.L201Q | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV55806292; called by muse, mutect2, varscan2
- CLVS1 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.491); catalogued as COSV100370493; called by muse, mutect2, varscan2
- CNIH3 | c.153G>A p.R51= | Splice Region (SNP) | VAF 65/180 reads (36%) | catalogued as COSV55277831; called by muse, mutect2, varscan2
- CNKSR1 | c.1740G>A p.M580I (on ENST00000374253 / NM_001297647.2; = p.M573I on NM_006314.3) | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV58793846; called by muse, mutect2, varscan2
- CNTN1 | c.2262G>A p.W754* | Nonsense Mutation (SNP) | VAF 9/63 reads (14%) | catalogued as COSV61642321; called by muse, mutect2, varscan2
- CNTN5 | c.139G>A p.G47S | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.027); catalogued as rs529404054, COSV54331232; called by muse, mutect2, varscan2
- CNTN5 | c.2317C>T p.P773S | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV54280099; called by muse, mutect2
- COL17A1 | c.2949G>A p.G983= | Splice Region (SNP) | VAF 29/153 reads (19%) | catalogued as COSV100793385, COSV62228022; called by muse, mutect2, varscan2
- COL22A1 | c.2978G>A p.G993E | Missense Mutation (SNP) | VAF 55/161 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1397519330, COSV57346993; called by muse, mutect2, varscan2
- COL22A1 | c.2042G>A p.G681D | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200915255, COSV57347002; called by muse, mutect2, varscan2
- COL3A1 | c.3001C>T p.P1001S | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs777180110, COSV58581928; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A4 | c.2270G>A p.G757E | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61629944; called by muse, mutect2, varscan2
- COL4A4 | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.782); catalogued as rs372841765, COSV100307718, COSV61634147; called by muse, mutect2, varscan2
- COL5A1 | c.4048C>T p.P1350S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.541); catalogued as rs762699995, COSV65671736; called by muse, mutect2, varscan2
- COL5A3 | c.2650G>A p.G884S | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53414541; called by muse, mutect2
- COL6A3 | c.2499G>A p.E833= | Splice Region (SNP) | VAF 21/65 reads (32%) | catalogued as COSV104402600, COSV55098060; called by muse, mutect2, varscan2
- COLEC11 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.308); catalogued as COSV52595308, COSV99363797; called by muse, mutect2
- CORO1A | c.321G>A p.M107I | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.763); catalogued as COSV54631626; called by muse, mutect2, varscan2
- CORO7 | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs759601582, COSV52028817; called by muse, mutect2, varscan2
- COX10 | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); catalogued as COSV55406535; called by muse, mutect2, varscan2
- CPA1 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50571860; called by muse, mutect2, varscan2
- CPA6 | c.998C>T p.P333L | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753122064, COSV52735585; called by muse, mutect2, varscan2
- CPAMD8 | c.645G>A p.L215= (on ENST00000651564; = p.L168= on NM_015692.5) | Splice Region (SNP) | VAF 33/162 reads (20%) | catalogued as COSV52236864; called by muse, mutect2, varscan2
- CPS1 | c.1289C>T p.S430L | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51810862; called by muse, mutect2, varscan2
- CPSF1 | c.3277G>A p.E1093K | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.378); catalogued as COSV58234530; called by muse, mutect2, varscan2
- CPSF6 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.353); catalogued as rs1364684513, COSV57012505; called by muse, mutect2, varscan2
- CRB1 | c.2110G>A p.G704S | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66331702; called by muse, mutect2, varscan2
- CRHR2 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.159); catalogued as COSV59266480; called by muse, mutect2
- CRNN | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 26/236 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV55122885; called by muse, mutect2, varscan2
- CRTAC1 | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54005029; called by muse, mutect2, varscan2
- CSF2RA | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs200259335, COSV62625546; called by muse, mutect2, varscan2
- CSMD1 | c.7880C>T p.S2627F (on ENST00000520002; = p.S2626F on NM_033225.6) | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs267601891, COSV59284813; called by muse, mutect2, varscan2
- CSMD1 | c.3229C>T p.R1077C (on ENST00000520002; = p.R1076C on NM_033225.6) | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867742507, COSV59279573, COSV59288383; called by muse, mutect2, varscan2
- CSMD2 | c.8506G>A p.G2836S | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (1); PolyPhen probably damaging (0.992); catalogued as rs199535455, COSV53932489; called by muse, mutect2, varscan2
- CSMD2 | c.7538C>T p.P2513L | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.862); catalogued as rs1367866246, COSV53932510; called by muse, mutect2, varscan2
- CSMD2 | c.2128G>A p.G710S | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53932523; called by muse, mutect2, varscan2
- CSMD3 | c.1208A>T p.N403I | Missense Mutation (SNP) | VAF 57/141 reads (40%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.177); catalogued as COSV52241389; called by muse, mutect2, varscan2
- CSMD3 | c.1009G>A p.G337R | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52241410, COSV99835832; called by muse, varscan2
- CSMD3 | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs755471454, COSV52241436; called by muse, varscan2
- CTNNA2 | c.1082C>T p.P361L | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV58164040; called by muse, mutect2, varscan2
- CTNNA3 | c.1964G>A p.G655E | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as COSV65602106; called by muse, mutect2, varscan2
- CTNND2 | c.998C>T p.S333L | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as COSV58864015; called by muse, mutect2, varscan2
- CTNND2 | c.170A>G p.E57G | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100479964; called by muse, mutect2, varscan2
- CTNND2 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs867961714, COSV58890608; called by muse, mutect2, varscan2
- CUX1 | c.3898C>T p.R1300C | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV52894321, COSV52906147; called by muse, mutect2, varscan2
- CWH43 | c.1439C>T p.T480I | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as COSV56941085; called by muse, mutect2, varscan2
- CYLC2 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.639); catalogued as COSV66336158; called by muse, mutect2, varscan2
- CYP19A1 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as rs867525000, COSV53060764; called by muse, mutect2, varscan2
- CYP19A1 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1411620450, COSV53060773; called by muse, varscan2
- CYP27C1 | c.928C>T p.P310S | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58867363; called by muse, mutect2, varscan2
- CYP2C9 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.429); catalogued as rs1003768765, COSV53246284; called by muse, mutect2, varscan2
- CYP2S1 | c.1385C>T p.S462F | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.572); catalogued as COSV100027574; called by mutect2, varscan2
- CYP3A43 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.433); catalogued as COSV55936966; called by muse, mutect2, varscan2
- CYP4V2 | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV66506748; called by muse, mutect2, varscan2
- CYP4X1 | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64151222; called by muse, mutect2, varscan2
- CYP4Z1 | c.1448C>T p.P483L | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.069); catalogued as rs200917257, COSV61965813; called by muse, mutect2, varscan2
- CYP7B1 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59592582, COSV59594156; called by muse, mutect2, varscan2
- DBT | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV64495889; called by muse, mutect2, varscan2
- DCANP1 | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.27); catalogued as COSV72345868; called by muse, mutect2, varscan2
- DCHS1 | c.1816G>A p.D606N | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100202460; called by muse, mutect2, varscan2
- DCT | c.653C>T p.T218I | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV100986279; called by muse, mutect2, varscan2
- DDB1 | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 39/237 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.358); catalogued as rs1350960678, COSV57104287; called by muse, mutect2, varscan2
- DDX1 | c.1432G>A p.G478S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.077); catalogued as COSV51841161; called by muse, mutect2
- DHX9 | c.3215C>T p.S1072F | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV62360708; called by muse, mutect2
- DIDO1 | c.6428C>T p.S2143F | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.201); catalogued as COSV56628104; called by muse, mutect2, varscan2
- DMBT1 | c.3238C>A p.H1080N (on ENST00000338354 / NM_001377530.1; = p.H581N on NM_004406.3) | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.713); catalogued as COSV57539449, COSV57551510; called by muse, mutect2, varscan2
- DNAH11 | c.12683C>T p.T4228I | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.159); catalogued as COSV60966271; called by muse, mutect2, varscan2
- DNAH14 | c.898G>A p.G300R (on ENST00000445597; = p.G173R on NM_144989.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/184 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV64781899; called by muse, mutect2, varscan2
- DNAH17 | c.3390G>A p.M1130I | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.194); catalogued as rs189737946, COSV67758186; called by muse, mutect2, varscan2
- DNAH5 | c.10281G>A p.K3427= | Splice Region (SNP) | VAF 13/41 reads (32%) | catalogued as COSV54219840, COSV54238484; called by muse, mutect2, varscan2
- DNAH5 | c.8020G>A p.E2674K | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868830185, COSV54238491; called by muse, mutect2, varscan2
- DNAH6 | c.1915C>T p.Q639* | Nonsense Mutation (SNP) | VAF 14/81 reads (17%) | catalogued as COSV52865604; called by muse, mutect2, varscan2
- DNAH7 | c.5621G>A p.R1874Q | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as rs1274108178, COSV56774235; called by muse, mutect2, varscan2
- DNAH8 | c.8942G>A p.W2981* | Nonsense Mutation (SNP) | VAF 19/95 reads (20%) | catalogued as COSV59463111; called by muse, mutect2, varscan2
- DNM2 | c.2362A>T p.T788S (on ENST00000355667 / NM_001005360.3; = p.T784S on NM_004945.3) | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.092); catalogued as rs755864859, COSV99284254; called by muse, mutect2, varscan2
- DNM2 | c.2363C>T p.T788I (on ENST00000355667 / NM_001005360.3; = p.T784I on NM_004945.3) | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.073); catalogued as rs763624831, COSV99284255; called by muse, mutect2, varscan2
- DNMT1 | c.3974C>T p.P1325L | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61577076; called by muse, mutect2, varscan2
- DOK6 | c.965G>A p.G322E | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.104); catalogued as rs866303972, COSV66934143, COSV99059943; called by muse, mutect2, varscan2
- DRICH1 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.033); catalogued as COSV58504291; called by muse, varscan2
- DSC2 | c.1440G>A p.M480I | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51866920; called by muse, mutect2, varscan2
- DSCAM | c.5721G>A p.M1907I | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.838); catalogued as COSV68029944; called by muse, varscan2
- DSCAM | c.2788G>A p.D930N | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.258); catalogued as COSV68031123; called by muse, mutect2, varscan2
- DSCAM | c.2311G>A p.D771N | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.12); catalogued as rs267606128, COSV68029375; called by muse, mutect2, varscan2
- DSPP | c.239G>A p.G80E | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.054); catalogued as rs905226892, COSV99217799; called by muse, mutect2, varscan2
- DYSF | c.938-1G>A p.X313_splice | Splice Site (SNP) | VAF 22/91 reads (24%) | catalogued as CS123553, COSV50474546; called by muse, mutect2, varscan2
- E2F2 | c.571C>T p.Q191* | Nonsense Mutation (SNP) | VAF 19/67 reads (28%) | catalogued as COSV100674859; called by muse, mutect2, varscan2
- EARS2 | c.1316C>T p.S439L | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs747235837, COSV71942907; called by muse, mutect2, varscan2
- ECEL1 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0.078); catalogued as rs1448162943, COSV58811963, COSV58813337; called by muse, mutect2, varscan2
- EFCAB2 | c.703C>T p.R235* (on ENST00000366522; = p.R99* on NM_032328.3) | Nonsense Mutation (SNP) | VAF 41/97 reads (42%) | catalogued as rs149676779, COSV63657102; called by muse, mutect2, varscan2
- EFCAB6 | c.4472C>T p.S1491F | Missense Mutation (SNP) | VAF 76/178 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV53067277; called by muse, mutect2, varscan2
- EFCAB6 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV53067286; called by muse, mutect2, varscan2
- EFNB3 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754577204; called by muse, mutect2, varscan2
- EIF2AK3 | c.2476C>T p.R826* | Nonsense Mutation (SNP) | VAF 43/133 reads (32%) | catalogued as rs755001234, COSV57549840; called by muse, mutect2, varscan2
- EIF4A3 | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV53921164; called by muse, mutect2, varscan2
- ELN | c.572G>A p.G191E | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52712642; called by muse, mutect2, varscan2
- ELP4 | c.950G>A p.R317H (on ENST00000350638; = p.R316H on NM_019040.5) | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as rs749842817, COSV63355256; called by muse, mutect2, varscan2
- EML5 | c.1975G>A p.E659K | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.297); catalogued as COSV61348546; called by muse, mutect2, varscan2
- ENPEP | c.1055C>T p.P352L | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54453814; called by muse, mutect2, varscan2
- EPB41L1 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754822027, COSV52435165; called by muse, mutect2, varscan2
- EPHA6 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 53/292 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750297483, COSV67556787; called by muse, mutect2, varscan2
- EPHA8 | c.2573C>T p.P858L | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as rs1191247338, COSV51277731; called by muse, mutect2, varscan2
- EPHB6 | c.1195C>T p.R399* | Nonsense Mutation (SNP) | VAF 8/27 reads (30%) | catalogued as rs1445358080, COSV67418718; called by muse, mutect2, varscan2
- ERCC4 | c.1805C>T p.P602L | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.59); catalogued as rs1250391663, COSV61312920; called by muse, varscan2
- ESRP1 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.414); catalogued as COSV64407953; called by muse, mutect2, varscan2
- EXD1 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.086); catalogued as COSV59255218; called by muse, mutect2, varscan2
- F13B | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 29/169 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.936); catalogued as COSV66374751; called by muse, mutect2, varscan2
- FAM135B | c.772C>T p.H258Y | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52738638, COSV99428427; called by muse, mutect2, varscan2
- FAM155A | c.1208C>T p.S403L | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.324); catalogued as rs1389712905, COSV65555184; called by muse, mutect2, varscan2
- FAM168B | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV66304383; called by muse, mutect2, varscan2
- FAM186B | c.2641G>A p.G881R | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV57722271; called by muse, mutect2, varscan2
- FAM83D | c.1481C>T p.P494L | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs537005574, COSV54158147, COSV99465516; called by muse, mutect2, varscan2
- FAM83E | c.833G>A p.S278N | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV52377285; called by muse, mutect2
- FAM83G | c.1489G>A p.D497N | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV58760026; called by muse, mutect2, varscan2
- FANCG | c.163C>T p.H55Y | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.011); catalogued as COSV66213913; called by muse, mutect2, varscan2
- FAT3 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53073120; called by muse, mutect2, varscan2
- FAT3 | c.5290G>A p.D1764N | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53141157; called by muse, mutect2, varscan2
- FAT4 | c.2644A>C p.T882P | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV67892923; called by muse, mutect2, varscan2
- FAT4 | c.6470C>T p.A2157V | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.168); catalogued as rs747900958, COSV58696559; called by muse, mutect2, varscan2
- FBXO24 | c.1427T>C p.I476T (on ENST00000241071 / NM_033506.3; = p.I514T on NM_012172.5) | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV53827731; called by muse, mutect2, varscan2
- FBXO28 | c.299G>T p.R100I | Missense Mutation (SNP) | VAF 64/147 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV64800921; called by muse, mutect2, varscan2
- FBXW12 | c.1124G>A p.R375Q | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs768488061, COSV56484657; called by muse, mutect2, varscan2
- FCHO2 | c.1462A>T p.S488C | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); catalogued as COSV59274989; called by muse, mutect2, varscan2
- FCRL6 | c.1108G>A p.V370I | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58941829; called by muse, mutect2, varscan2
- FGFR1 | c.2295G>A p.E765= (on ENST00000447712 / NM_023110.3; = p.E763= on NM_015850.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 5/49 reads (10%) | catalogued as COSV58339099; called by muse, mutect2, varscan2
- FGL2 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.174); catalogued as COSV50383477; called by muse, mutect2, varscan2
- FHOD1 | c.724C>A p.R242S | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV50763829; called by muse, mutect2, varscan2
- FIP1L1 | c.358C>T p.L120F | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.534); catalogued as COSV60998088; called by muse, mutect2, varscan2
- FLG | c.6859G>A p.E2287K | Missense Mutation (SNP) | VAF 92/720 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.018); catalogued as rs199574917; called by muse, mutect2, varscan2
- FLG | c.5108C>T p.S1703L | Missense Mutation (SNP) | VAF 99/818 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV64244649; called by muse, mutect2, varscan2
- FLG | c.3167C>T p.S1056F | Missense Mutation (SNP) | VAF 447/1135 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as rs1323308519, COSV64244653; called by muse, mutect2, varscan2
- FLG2 | c.3445G>A p.G1149S | Missense Mutation (SNP) | VAF 171/357 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.026); catalogued as COSV66170585; called by muse, mutect2, varscan2
- FLNA | c.1399C>T p.R467C | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs367948333, COSV61047133; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLNC | c.7550G>A p.G2517E | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.315); catalogued as COSV57959719; called by muse, mutect2
- FMOD | c.902C>A p.S301Y | Missense Mutation (SNP) | VAF 102/201 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61610348; called by muse, mutect2, varscan2
- FNDC1 | c.2308C>T p.H770Y | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.134); catalogued as COSV51942750; called by muse, mutect2, varscan2
- FRAS1 | c.4962G>A p.M1654I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.184); catalogued as COSV53626786; called by muse, mutect2, varscan2
- FRAS1 | c.5671C>T p.R1891C | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as rs373573150; called by muse, mutect2
- FRAS1 | c.6503G>A p.G2168E | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs267600270, COSV53626842; called by muse, mutect2, varscan2
- FRAS1 | c.7339G>A p.G2447R | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53626867; called by muse, mutect2, varscan2
- FREM1 | c.604C>T p.Q202* | Nonsense Mutation (SNP) | VAF 18/45 reads (40%) | catalogued as COSV66525113; called by muse, mutect2, varscan2
- FREM2 | c.6670A>T p.S2224C | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV54843836; called by muse, mutect2, varscan2
- FRS3 | c.301C>T p.L101F | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52485526; called by muse, mutect2, varscan2
- FRYL | c.3308G>A p.R1103K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.626); catalogued as COSV99977781; called by muse, mutect2, varscan2
- FYTTD1 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs772495686, COSV54084854; called by muse, mutect2, varscan2
- GABBR2 | c.1270G>A p.G424R | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52311262, COSV99411191; called by muse, mutect2, varscan2
- GABRA6 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs377669113; called by muse, mutect2, varscan2
- GABRG1 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1239800695, COSV54951118; called by muse, mutect2, varscan2
- GABRP | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.045); catalogued as COSV54664054; called by mutect2, varscan2
- GASK1B | c.1084C>T p.H362Y | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV56709198; called by muse, mutect2, varscan2
- GDF5 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 69/166 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1441020967, COSV65502341; called by muse, mutect2, varscan2
- GGH | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV52651176; called by muse, mutect2, varscan2
- GHR | c.1232T>C p.V411A | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.401); catalogued as COSV50119607; called by muse, mutect2, varscan2
- GHR | c.1505C>T p.S502F | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50119665; called by muse, mutect2, varscan2
- GIMAP2 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 57/101 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56234860, COSV99785519; called by muse, mutect2, varscan2
- GIMAP4 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as rs755169219, COSV55433636; called by muse, mutect2, varscan2
- GIMAP7 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 53/88 reads (60%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs200815148, COSV57958459; called by muse, mutect2, varscan2
- GLP1R | c.1240C>T p.R414W | Missense Mutation (SNP) | VAF 47/283 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs199796313, COSV64714509, COSV64715892; called by muse, mutect2, varscan2
- GMPS | c.938C>T p.S313L | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV55810555; called by muse, mutect2
- GOLM1 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as COSV57415322; called by muse, mutect2, varscan2
- GP2 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as rs200111828, COSV56895251, COSV56896013; called by muse, mutect2, varscan2
- GPATCH8 | c.3107C>T p.P1036L | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1436563680, COSV59196086; called by muse, mutect2, varscan2
- GPR162 | c.527G>A p.G176D | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV50592700; called by muse, mutect2, varscan2
- GPR162 | c.1283C>T p.S428F (on ENST00000311268 / NM_019858.2; = p.S144F on NM_014449.2) | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.221); catalogued as rs782312229, COSV99301473; called by muse, mutect2, varscan2
- GPR50 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as rs374353730, COSV54439920; called by muse, mutect2, varscan2
- GPR63 | c.264G>A p.M88I | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.091); catalogued as COSV57742245; called by muse, mutect2, varscan2
- GRIA3 | c.466T>A p.Y156N | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52070751; called by muse, mutect2, varscan2
- GRIK4 | c.2198G>A p.R733Q | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); catalogued as rs761713343, COSV70804414; called by mutect2, varscan2
- GRK7 | c.1076C>T p.P359L | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1258368707, COSV53823960; called by muse, mutect2, varscan2
- H2BW1 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV54220784; called by muse, mutect2, varscan2
- HAP1 | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV57879389; called by muse, mutect2, varscan2
- HARS1 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56908071; called by muse, mutect2, varscan2
- HBA1 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs34472107, COSV52265847; ClinVar: other; called by muse, mutect2
- HCAR3 | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.901); catalogued as COSV63675979; called by muse, mutect2, varscan2
- HCLS1 | c.1328G>A p.G443E | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV57523477; called by muse, mutect2, varscan2
- HECTD4 | c.11422G>A p.D3808N | Missense Mutation (SNP) | VAF 4/73 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.182); catalogued as COSV66395479; called by muse, mutect2
- HECW2 | c.1804G>A p.D602N | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.2); catalogued as rs765958118, COSV53666048; called by muse, mutect2, varscan2
- HELZ | c.4904A>T p.N1635I | Missense Mutation (SNP) | VAF 37/201 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); catalogued as COSV62379487; called by muse, mutect2, varscan2
- HELZ2 | c.457C>T p.L153F | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.027); catalogued as COSV64410052; called by muse, mutect2, varscan2
- HEPH | c.3329C>T p.S1110F (on ENST00000343002; = p.S843F on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as rs750168109, COSV57967548; called by muse, mutect2, varscan2
- HHIP | c.613G>A p.V205M | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.181); catalogued as COSV99667690; called by muse, mutect2, varscan2
- HHLA2 | c.304G>T p.G102W | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63317731; called by muse, mutect2, varscan2
- HID1 | c.2318C>T p.P773L | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60913992; called by muse, mutect2
- HIPK3 | c.1568C>T p.P523L | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV57563817; called by muse, mutect2, varscan2
- HIVEP1 | c.7279A>T p.T2427S | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV101045596; called by muse, mutect2, varscan2
- HIVEP1 | c.7280C>T p.T2427M | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs752541780, COSV101045598; called by muse, mutect2, varscan2
- HIVEP3 | c.2170G>A p.E724K | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV56018774; called by muse, mutect2, varscan2
- HOMER1 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1247313392, COSV56528269; called by muse, mutect2, varscan2
- HRNR | c.6619C>T p.R2207C | Missense Mutation (SNP) | VAF 100/1239 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1486639714, COSV64260280; called by muse, varscan2
- HRNR | c.5728G>A p.G1910S | Missense Mutation (SNP) | VAF 214/3980 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs757430987, COSV64260283; called by muse, mutect2
- HSD3B1 | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as rs1242815235, COSV52491422; called by muse, mutect2, varscan2
- HSD3B2 | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV65593613; called by muse, mutect2, varscan2
- HTN1 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.515); catalogued as COSV55894917; called by muse, mutect2, varscan2
- HYDIN | c.8141G>A p.G2714E | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); catalogued as rs775914794, COSV59263281; called by muse, mutect2, varscan2
- IFNA16 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as COSV66510056; called by muse, mutect2
- IGBP1 | c.840A>C p.L280F | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.429); catalogued as COSV60556805; called by muse, mutect2
- IGBP1 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs200563299, COSV60556812; called by muse, mutect2
- IGFBP1 | c.516G>A p.W172* | Nonsense Mutation (SNP) | VAF 25/136 reads (18%) | catalogued as COSV51875060; called by muse, mutect2, varscan2
- IGHV3-21 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 54/330 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.414); catalogued as rs1555459135; called by muse, varscan2
- IGSF3 | c.1610C>T p.S537F (on ENST00000369486 / NM_001007237.3; = p.S557F on NM_001542.4) | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV59587800; called by muse, mutect2, varscan2
- IHH | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367575081, COSV99838819; called by muse, mutect2, varscan2
- IL18RAP | c.181C>T p.R61* | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | catalogued as rs867163754, COSV51825422; called by muse, mutect2, varscan2
- IL18RAP | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.031); catalogued as COSV51827448; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1616G>A p.W539* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as COSV56279103; called by muse, mutect2, varscan2
- IL31RA | c.2284G>A p.G762R | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV61695436; called by muse, mutect2, varscan2
- IL36B | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); catalogued as rs267598838, COSV52084862; called by muse, mutect2, varscan2
- IL37 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 62/316 reads (20%) | SIFT tolerated (0.68); PolyPhen benign (0.139); catalogued as rs775151709, COSV54492017; called by muse, varscan2
- IL37 | c.358C>T p.L120F | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54492052; called by muse, varscan2
- ILDR1 | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56551674, COSV99878863; called by muse, mutect2, varscan2
- IMP4 | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147137797; called by muse, mutect2, varscan2
- INAVA | c.1264C>T p.P422S | Missense Mutation (SNP) | VAF 105/657 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV66257120; called by muse, mutect2, varscan2
- INHBB | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs144228850; called by muse, mutect2, varscan2
- INHBC | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.88); PolyPhen benign (0.025); catalogued as COSV59005673; called by muse, mutect2, varscan2
- INMT | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1310530578, COSV50001892; called by muse, mutect2, varscan2
- INSC | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as COSV65411699; called by muse, mutect2, varscan2
- INSIG1 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 23/219 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100453067; called by muse, mutect2
- INSR | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.608); catalogued as COSV57160507; called by muse, mutect2, varscan2
- INSRR | c.1691C>T p.S564F | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.119); catalogued as rs1424704699, COSV63875288; called by muse, mutect2, varscan2
- IP6K2 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.687); catalogued as COSV60794583; called by muse, mutect2, varscan2
- IPO4 | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.074); catalogued as rs1311818690, COSV99938220; called by muse, mutect2, varscan2
- IPO4 | c.841-1G>A p.X281_splice | Splice Site (SNP) | VAF 25/114 reads (22%) | catalogued as COSV99938221; called by muse, mutect2, varscan2
- IPO7 | c.2182G>A p.G728R | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.866); catalogued as COSV65686010; called by muse, mutect2, varscan2
- IQSEC3 | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV58287413; called by muse, mutect2
- IRAG1 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as COSV70212088; called by muse, mutect2, varscan2
- ITGA3 | c.2177C>T p.T726I | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); catalogued as COSV50320995; called by muse, mutect2, varscan2
- ITPRIPL2 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.406); catalogued as rs541259036, COSV67347878; called by muse, mutect2, varscan2
- JUP | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 70/197 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60278932; called by muse, mutect2, varscan2
- KANK4 | c.2719G>A p.D907N | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs752600367, COSV58093371; called by muse, mutect2, varscan2
- KAZALD1 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100930613; called by muse, mutect2, varscan2
- KCNA2 | c.968C>T p.A323V | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100316086; called by muse, mutect2, varscan2
- KCNB1 | c.2389T>A p.F797I | Missense Mutation (SNP) | VAF 61/354 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); catalogued as COSV100870399, COSV65569558; called by muse, mutect2, varscan2
- KCNG2 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.932); catalogued as COSV60268968; called by muse, mutect2
- KCNK10 | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.881); catalogued as rs766661666, COSV56646831; called by muse, mutect2, varscan2
- KCNQ3 | c.1225C>T p.P409S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV66475740; called by muse, mutect2, varscan2
- KDELR1 | c.277T>C p.F93L | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.107); catalogued as COSV58102518; called by muse, varscan2
- KDM1B | c.1856A>G p.Y619C (on ENST00000449850; = p.Y386C on NM_153042.4) | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV52812591; called by muse, mutect2, varscan2
- KDR | c.3196C>T p.R1066C | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757722266, COSV55767979; called by muse, mutect2, varscan2
- KHDC1 | c.505C>T p.H169Y (on ENST00000370384 / NM_001251874.2; = p.H96Y on NM_030568.5) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV57615413; called by muse, mutect2, varscan2
- KIAA0408 | c.307A>C p.K103Q | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.259); catalogued as COSV64107531; called by muse, mutect2, varscan2
- KIAA0753 | c.1705C>T p.P569S | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1349814240, COSV63818035; called by muse, mutect2, varscan2
- KIAA0895 | c.1426C>T p.R476C (on ENST00000297063 / NM_001100425.2; = p.R425C on NM_015314.3) | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51712164; called by muse, mutect2, varscan2
- KIF21B | c.2483C>T p.P828L | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV100144974; called by muse, mutect2
- KIF21B | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as COSV59761381; called by muse, mutect2
- KIF2A | c.1208A>G p.E403G | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.315); catalogued as COSV66946085; called by muse, mutect2, varscan2
- KIF2B | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.068); catalogued as rs868793706, COSV52127761; called by muse, mutect2, varscan2
- KIRREL1 | c.1115G>A p.R372Q | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as rs1405619267, COSV63289056, COSV63290528; called by muse, mutect2, varscan2
- KLHDC7B | c.925C>T p.P309S (on ENST00000395676; = p.P950S on NM_138433.5) | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.143); catalogued as COSV67464913; called by muse, mutect2, varscan2
- KLK6 | c.707G>A p.W236* | Nonsense Mutation (SNP) | VAF 42/152 reads (28%) | catalogued as COSV59566112; called by muse, mutect2, varscan2
- KLK7 | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58344594; called by muse, mutect2, varscan2
- KLRC2 | c.188-1G>A p.X63_splice | Splice Site (SNP) | VAF 16/152 reads (11%) | catalogued as rs762361475, COSV67900181; called by muse, mutect2
- KMT2C | c.7394C>T p.P2465L | Missense Mutation (SNP) | VAF 33/270 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as COSV51466302; called by muse, mutect2, varscan2
- KRT3 | c.948G>A p.M316I | Missense Mutation (SNP) | VAF 60/284 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as COSV58815120; called by muse, mutect2, varscan2
- KRT32 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs141728288; called by muse, mutect2, varscan2
- KRT6C | c.1535G>A p.G512E | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as COSV52878780; called by muse, mutect2, varscan2
- KRT9 | c.1433G>A p.R478Q | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs376407648, COSV55855080; called by muse, mutect2
- KRTAP10-2 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 36/195 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV59970116; called by muse, mutect2, varscan2
- KRTAP5-9 | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 51/234 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.914); catalogued as COSV73200163; called by muse, mutect2, varscan2
- KRTAP9-4 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV61898326; called by muse, mutect2, varscan2
- LAMB4 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV52724171; called by muse, mutect2, varscan2
- LAMP3 | c.961G>A p.G321R | Missense Mutation (SNP) | VAF 65/326 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200866582, COSV55615729; called by muse, mutect2, varscan2
- LAYN | c.128G>A p.G43E (on ENST00000375615 / NM_001258390.1; = p.G35E on NM_178834.5) | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV65105125; called by muse, mutect2, varscan2
- LBR | c.176C>T p.S59F | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.488); catalogued as COSV55290298; called by muse, mutect2
- LCT | c.4355C>T p.S1452F | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51553279; called by muse, mutect2, varscan2
- LCTL | c.923G>A p.G308E | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.922); catalogued as rs796891269, COSV57181506; called by muse, mutect2, varscan2
- LDB3 | c.1057C>T p.P353S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV53945580; called by muse, mutect2
- LHX6 | c.983G>A p.G328E (on ENST00000373755 / NM_001242334.2; = p.G357E on NM_014368.5) | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as COSV61344654; called by muse, mutect2, varscan2
- LIFR | c.60G>A p.M20I | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.023); catalogued as COSV54694296; called by muse, mutect2, varscan2
- LIG1 | c.2464C>T p.P822S | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1349395135, COSV54393741; called by muse, mutect2
- LILRA1 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.057); catalogued as rs530732441, COSV52182590; called by muse, varscan2
- LILRB4 | c.857G>A p.G286E | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.81); catalogued as rs776706290, COSV54405403; called by muse, mutect2
- LLCFC1 | c.167C>T p.P56L (on ENST00000458732; = p.P25L on NM_178829.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); catalogued as COSV62335255; called by muse, mutect2, varscan2
- LPA | c.3796G>A p.E1266K | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV60305343; called by muse, mutect2, varscan2
- LPAR3 | c.184C>T p.H62Y | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65454229; called by muse, mutect2, varscan2
- LRIG1 | c.2251C>T p.Q751* | Nonsense Mutation (SNP) | VAF 14/93 reads (15%) | catalogued as COSV56244004; called by muse, mutect2, varscan2
- LRIG1 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs147639877, COSV56250668; called by muse, mutect2, varscan2
- LRP1B | c.9458C>T p.P3153L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755990557, COSV67217005; called by muse, mutect2, varscan2
- LRP1B | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs776305678, COSV67188037; called by muse, mutect2, varscan2
- LRP2 | c.12320G>A p.G4107E | Missense Mutation (SNP) | VAF 44/250 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as rs1479138919, COSV55562165; called by muse, mutect2, varscan2
- LRP2 | c.7295G>A p.R2432K | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.469); catalogued as COSV55541796, COSV55562174; called by muse, mutect2, varscan2
- LRRC49 | c.413C>T p.S138L | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs377618599; called by muse, mutect2, varscan2
- LSM10 | c.193C>A p.H65N | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.034); catalogued as COSV59872505; called by muse, mutect2, varscan2
- LTA | c.61C>T p.L21F | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs867878229, COSV69305068; called by muse, mutect2, varscan2
- LY6H | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV61370373; called by muse, mutect2, varscan2
- LYN | c.785G>A p.W262* | Nonsense Mutation (SNP) | VAF 16/125 reads (13%) | catalogued as COSV70206032; called by muse, varscan2
- MAEL | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 74/151 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63112269; called by muse, mutect2, varscan2
- MAGEA10 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV54883060; called by muse, mutect2, varscan2
- MAGEC1 | c.2839C>T p.P947S | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs763285093, COSV53567836, COSV53577256; called by muse, mutect2, varscan2
- MAGI2 | c.2038C>T p.H680Y | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as COSV100836332, COSV62679023; called by muse, mutect2, varscan2
- MAN2C1 | c.2143G>A p.E715K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.208); catalogued as COSV99145716; called by muse, mutect2
- MAP10 | c.2945T>C p.L982S | Missense Mutation (SNP) | VAF 127/246 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.207); catalogued as rs765784275, COSV69364214; called by muse, mutect2, varscan2
- MAP6 | c.2300C>T p.P767L | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.162); catalogued as COSV59076730, COSV59078240; called by muse, mutect2, varscan2
- MAP7D2 | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); catalogued as COSV65528718; called by muse, mutect2, varscan2
- MAP9 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV60905472; called by muse, mutect2, varscan2
- MARCHF10 | c.1684C>T p.L562F | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.641); catalogued as COSV60885312, COSV60889020; called by muse, mutect2, varscan2
- MATN4 | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 18/102 reads (18%) | PolyPhen probably damaging (0.999); catalogued as COSV59214829; called by muse, mutect2, varscan2
- MCHR2 | c.587G>A p.W196* | Nonsense Mutation (SNP) | VAF 19/80 reads (24%) | catalogued as rs867718088, COSV55999558; called by muse, mutect2, varscan2
- MCU | c.677G>A p.R226K | Missense Mutation (SNP) | VAF 50/265 reads (19%) | SIFT tolerated (0.96); PolyPhen benign (0.036); catalogued as COSV64067192; called by muse, mutect2, varscan2
- MED13L | c.3178C>T p.P1060S | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV56124528; called by muse, mutect2, varscan2
- MGAM | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 50/94 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs779098977, COSV71884967; called by muse, mutect2, varscan2
- MGAT4C | c.1225G>A p.G409R | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59833829, COSV59834880; called by muse, mutect2, varscan2
- MGLL | c.893G>A p.G298E (on ENST00000398104 / NM_001003794.2; = p.G308E on NM_007283.6) | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV54027563; called by muse, mutect2, varscan2
- MMD2 | c.529C>T p.L177F | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as rs774820274, COSV68661156; called by muse, mutect2, varscan2
- MMP26 | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs746261222, COSV56171975; called by muse, mutect2, varscan2
- MNDA | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as COSV100933231, COSV63741479, COSV63742108; called by muse, mutect2, varscan2
- MORC2 | c.2725G>A p.D909N (on ENST00000397641 / NM_001303256.3; = p.D847N on NM_014941.3) | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs770586964, COSV53200446; called by muse, mutect2
- MPP7 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs868690750, COSV61730420; called by muse, mutect2
- MRGPRX2 | c.617T>A p.L206Q | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61674531; called by muse, mutect2, varscan2
- MROH2B | c.2330C>T p.S777F | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as COSV68181333; called by muse, mutect2, varscan2
- MROH7 | c.1550C>T p.S517F | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1352054394, COSV100273799, COSV59868065; called by muse, mutect2
- MTF1 | c.1493G>A p.G498E | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.476); catalogued as COSV65989798; called by muse, mutect2, varscan2
- MTFR1L | c.774G>A p.L258= | Splice Region (SNP) | VAF 28/177 reads (16%) | catalogued as COSV65353117; called by muse, mutect2, varscan2
- MTR | c.2956G>A p.G986S | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100855501; called by muse, mutect2
- MTR | c.3262C>T p.P1088S | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs1459148876, COSV63965650; called by muse, mutect2, varscan2
- MUC16 | c.33104C>T p.S11035L | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.07); catalogued as rs1568739792, COSV67478941; called by muse, mutect2, varscan2
- MUC16 | c.19823C>T p.S6608L | Missense Mutation (SNP) | VAF 59/232 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs746016038, COSV67445814, COSV67466930; called by muse, mutect2, varscan2
- MUC16 | c.17551C>T p.P5851S | Missense Mutation (SNP) | VAF 37/203 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.035); catalogued as rs267605800, COSV67460962; called by muse, mutect2, varscan2
- MUC16 | c.11518C>T p.P3840S | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as rs207476998, COSV67478962; called by muse, mutect2, varscan2
- MUC16 | c.2393C>T p.S798L | Missense Mutation (SNP) | VAF 48/204 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.096); catalogued as rs759389533, COSV67448135; called by muse, mutect2, varscan2
- MUC17 | c.4748T>C p.M1583T | Missense Mutation (SNP) | VAF 65/371 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781446503; called by muse, mutect2, varscan2
- MUC17 | c.9658G>A p.G3220R | Missense Mutation (SNP) | VAF 91/502 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.062); catalogued as rs373571427; called by muse, mutect2, varscan2
- MUC4 | c.1690C>T p.Q564* | Nonsense Mutation (SNP) | VAF 77/336 reads (23%) | catalogued as COSV62166161; called by muse, mutect2, varscan2
- MYBPC2 | c.1805G>A p.S602N | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.388); catalogued as COSV63097562; called by muse, mutect2, varscan2
- MYH1 | c.4250C>T p.S1417F | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as COSV56844838; called by muse, mutect2, varscan2
- MYH11 | c.3299A>G p.D1100G | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as COSV55560694; called by muse, varscan2
- MYH15 | c.4210G>A p.E1404K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs267599527, COSV56306748; called by muse, mutect2
- MYH15 | c.389G>A p.W130* | Nonsense Mutation (SNP) | VAF 15/56 reads (27%) | catalogued as COSV56314557, COSV99841999; called by muse, mutect2, varscan2
- MYH2 | c.2943G>A p.V981= | Splice Region (SNP) | VAF 63/258 reads (24%) | catalogued as COSV55432675; called by muse, mutect2, varscan2
- MYH2 | c.2632G>A p.E878K | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as rs745357669, COSV55431560; called by muse, mutect2, varscan2
- MYH4 | c.4888G>A p.E1630K | Missense Mutation (SNP) | VAF 47/198 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55116538; called by muse, mutect2, varscan2
- MYH8 | c.2051C>T p.P684L | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV67968624; called by muse, mutect2, varscan2
- MYL12A | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.825); catalogued as COSV54182730; called by muse, mutect2, varscan2
- MYL2 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs1555257777, COSV57407493; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYL7 | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56268344; called by muse, mutect2
- MYO1F | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs369105985; called by muse, varscan2
- MYO7A | c.4964G>A p.R1655K | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV68685673; called by muse, mutect2, varscan2
- MYO9A | c.3118C>T p.L1040F | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100614116, COSV100614450; called by muse, mutect2, varscan2
- MYOM3 | c.1753G>A p.D585N | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); catalogued as rs140144262, COSV58392087; called by muse, mutect2, varscan2
- MYT1L | c.2015G>A p.G672E | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as COSV67725856, COSV67733816; called by muse, mutect2, varscan2
- NAALADL2 | c.1615C>T p.P539S | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.71); PolyPhen benign (0.011); catalogued as COSV69158138; called by muse, mutect2, varscan2
- NBEA | c.607C>T p.R203* | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | catalogued as COSV59781919; called by muse, mutect2
- NCAN | c.3431G>A p.W1144* | Nonsense Mutation (SNP) | VAF 24/98 reads (24%) | catalogued as COSV53054305; called by muse, mutect2, varscan2
- NCKAP1L | c.1862G>A p.R621Q | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.181); catalogued as rs759730685, COSV53203119; called by muse, mutect2, varscan2
- NEBL | c.1620G>A p.M540I | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs868708368, COSV65804441; called by muse, mutect2, varscan2
- NELL1 | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV54283572; called by muse, mutect2, varscan2
- NEU2 | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV52093331; called by muse, mutect2, varscan2
- NFE2 | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.532); catalogued as COSV56456221; called by muse, mutect2, varscan2
- NHS | c.1061G>A p.R354K | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV66277164, COSV66278507; called by muse, mutect2, varscan2
- NIN | c.5222C>G p.A1741G (on ENST00000382041 / NM_182946.1; = p.A1028G on NM_016350.4) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.997); catalogued as COSV55397086, COSV55397898; called by muse, mutect2, varscan2
- NLRP12 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.257); catalogued as COSV60750510; called by muse, mutect2, varscan2
- NLRP13 | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.99); catalogued as rs753708026, COSV61621590; called by muse, mutect2, varscan2
- NLRP14 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV55069500; called by muse, mutect2, varscan2
- NMUR2 | c.403C>T p.L135F | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54920915; called by muse, mutect2, varscan2
- NOD1 | c.228G>T p.Q76H | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV56113601; called by muse, mutect2, varscan2
- NOP58 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750188563, COSV51895393, COSV51895891; called by muse, mutect2, varscan2
- NPAP1 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1360179271, COSV61504773; called by muse, mutect2, varscan2
- NPAP1 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.778); catalogued as COSV61508831; called by muse, mutect2, varscan2
- NPAP1 | c.2749G>A p.G917R | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.961); catalogued as COSV100275945; called by muse, mutect2, varscan2
- NPAP1 | c.2750G>A p.G917E | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV100274916; called by muse, mutect2, varscan2
- NPAS2 | c.1832C>T p.P611L | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV59559698; called by muse, mutect2, varscan2
- NPAS4 | c.2101G>A p.D701N | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as COSV60651481; called by muse, mutect2, varscan2
- NPR3 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV54090080; called by muse, mutect2, varscan2
- NPSR1 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.073); catalogued as COSV62204103; called by muse, mutect2, varscan2
- NR1I2 | c.27G>A p.W9* | Nonsense Mutation (SNP) | VAF 13/85 reads (15%) | catalogued as COSV61978005, COSV61978348; called by muse, mutect2, varscan2
- NRAP | c.4603C>T p.P1535S (on ENST00000359988 / NM_001322945.2; = p.P1500S on NM_006175.4) | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); catalogued as COSV63492310; called by muse, mutect2, varscan2
- NUF2 | c.123G>A p.K41= | Splice Region (SNP) | VAF 56/124 reads (45%) | catalogued as COSV54845064; called by muse, mutect2, varscan2
- NUP210L | c.3401G>A p.G1134E | Missense Mutation (SNP) | VAF 67/161 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV55152134; called by muse, mutect2, varscan2
- OBSL1 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54724558; called by muse, mutect2, varscan2
- OGA | c.2173G>A p.E725K | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as COSV63382339; called by muse, mutect2, varscan2
- OLFML3 | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV57436375; called by muse, mutect2, varscan2
- OR10G3 | c.638C>T p.S213F | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs775702742, COSV57810724; called by muse, mutect2, varscan2
- OR10H1 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.017); catalogued as COSV58471486; called by muse, mutect2, varscan2
- OR10J3 | c.163C>T p.H55Y | Missense Mutation (SNP) | VAF 146/295 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.066); catalogued as COSV59954498, COSV59954984, COSV59955013; called by muse, mutect2, varscan2
- OR10Q1 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV57471205; called by muse, mutect2, varscan2
- OR10W1 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.451); catalogued as COSV67720639; called by muse, mutect2, varscan2
- OR1C1 | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as COSV101376285, COSV68715934; called by muse, mutect2, varscan2
- OR2A7 | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 67/388 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV71827891; called by muse, mutect2, varscan2
- OR2M2 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 151/428 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as COSV62897957; called by mutect2, varscan2
- OR2T1 | c.131T>C p.M44T | Missense Mutation (SNP) | VAF 101/201 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as COSV63542441; called by muse, mutect2, varscan2
- OR2Y1 | c.809G>A p.G270E | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57137392; called by muse, mutect2, varscan2
- OR4A15 | c.799A>G p.K267E | Missense Mutation (SNP) | VAF 50/237 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV59036281; called by muse, mutect2, varscan2
- OR4M1 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 62/487 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as rs760327097, COSV60059765, COSV60060322, COSV60060528; called by muse, mutect2, varscan2
- OR4N2 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 40/366 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV60052985; called by muse, mutect2, varscan2
- OR51B2 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0.216); catalogued as COSV60915972; called by muse, mutect2, varscan2
- OR51I2 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV58298708, COSV58299400; called by muse, mutect2, varscan2
- OR52B4 | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0.042); catalogued as COSV68769216; called by muse, mutect2, varscan2
- OR56A4 | c.265C>T p.L89F | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.22); catalogued as COSV58109312; called by muse, mutect2, varscan2
- OR56B1 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 57/287 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV57723489; called by muse, mutect2, varscan2
- OR5K3 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 80/312 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV67349994; called by muse, mutect2, varscan2
- OR5R1 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56572951; called by muse, mutect2, varscan2
- OR5T2 | c.126G>A p.M42I | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV57589298; called by muse, mutect2, varscan2
- OR6C76 | c.671G>A p.R224K | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.023); catalogued as COSV60389443; called by muse, mutect2, varscan2
- OR7E24 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as COSV71702224; called by muse, mutect2, varscan2
- OR8A1 | c.170C>T p.T57I | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.027); catalogued as COSV52508849; called by muse, mutect2, varscan2
- OR8D1 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.185); catalogued as COSV63441945; called by muse, mutect2, varscan2
- OR8D1 | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV63442709; called by muse, mutect2, varscan2
- OR8D4 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as rs866009875, COSV58430971; called by muse, mutect2, varscan2
- OR8H3 | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs148197076, COSV57907799; called by muse, mutect2, varscan2
- OR8K5 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.84); catalogued as rs371957978, COSV57887956; called by muse, mutect2, varscan2
- OSBPL3 | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as COSV57659252; called by muse, mutect2, varscan2
- OSBPL6 | c.1160C>T p.S387F | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.991); catalogued as COSV51911486, COSV51923185; called by muse, mutect2, varscan2
- OSR1 | c.715G>A p.G239R | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.528); catalogued as COSV55345962; called by muse, mutect2, varscan2
- PADI3 | c.1115G>A p.R372K | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV64935593; called by muse, mutect2, varscan2
- PAPPA | c.3757G>A p.D1253N | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.889); catalogued as COSV60287525; called by muse, mutect2, varscan2
- PAPPA2 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 112/205 reads (55%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); catalogued as COSV62781781; called by muse, mutect2, varscan2
- PARD3 | c.3202C>T p.R1068* | Nonsense Mutation (SNP) | VAF 8/25 reads (32%) | catalogued as COSV61056190; called by muse, mutect2, varscan2
- PARP4 | c.2873G>A p.R958Q | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.766); catalogued as rs370048875, COSV67963054; called by muse, mutect2, varscan2
- PATL1 | c.1276C>T p.P426S | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55691097; called by muse, mutect2, varscan2
- PCDH15 | c.2290C>T p.R764C | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.849); catalogued as rs192813057, COSV57279849; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDH18 | c.665G>A p.G222E | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760575395, COSV61270099; called by muse, mutect2, varscan2
- PCDHA11 | c.1282G>A p.D428N | Missense Mutation (SNP) | VAF 49/250 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56524102; called by muse, mutect2, varscan2
- PCDHA12 | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.07); catalogued as COSV56480390; called by muse, varscan2
- PCDHA12 | c.982C>T p.P328S | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.572); catalogued as COSV56504501; called by muse, varscan2
- PCDHA12 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 48/221 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56524126; called by muse, mutect2, varscan2
- PCDHAC2 | c.2062C>T p.L688F | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.212); catalogued as rs1404451202, COSV53859401; called by muse, mutect2, varscan2
- PCDHB11 | c.1273G>A p.D425N | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV61309927; called by muse, mutect2, varscan2
- PCDHB13 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as COSV99507559; called by muse, mutect2, varscan2
- PCDHB14 | c.905A>G p.N302S | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as rs1178846459, COSV53389536; called by muse, mutect2, varscan2
- PCDHB15 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.109); catalogued as COSV50858685; called by muse, mutect2, varscan2
- PCDHB2 | c.1814C>T p.S605L | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99164107; called by muse, mutect2, varscan2
- PCDHB4 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 43/203 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1554274440, COSV52020064; called by muse, mutect2, varscan2
- PCDHB6 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as COSV50694999, COSV99170729; called by muse, mutect2, varscan2
- PCDHB8 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs782235899, COSV50769178; called by muse, mutect2
- PCDHB8 | c.1615T>A p.S539T | Missense Mutation (SNP) | VAF 30/432 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.93); catalogued as COSV99177250; called by muse, mutect2
- PCDHB8 | c.1616C>A p.S539Y | Missense Mutation (SNP) | VAF 31/431 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.429); catalogued as rs1554281314, COSV99177251; called by muse, mutect2
- PCDHGA9 | c.2144G>A p.R715K | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.013); catalogued as COSV53984858; called by muse, mutect2, varscan2
- PCDHGB2 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1164038678, COSV53952702; called by muse, mutect2, varscan2
- PCED1B | c.80G>A p.R27K | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71395453; called by muse, mutect2, varscan2
- PCLO | c.10876C>T p.P3626S | Missense Mutation (SNP) | VAF 61/174 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV61636468; called by muse, mutect2, varscan2
- PCLO | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV61648868; called by muse, mutect2, varscan2
- PCNX2 | c.4333C>T p.R1445* | Nonsense Mutation (SNP) | VAF 7/65 reads (11%) | catalogued as rs754419529, COSV50782807; called by muse, mutect2, varscan2
- PCYT1B | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV63265738; called by muse, mutect2, varscan2
- PDE11A | c.1100G>A p.G367E | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV53700788; called by muse, mutect2, varscan2
- PDE2A | c.1674T>G p.N558K | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as COSV57810114; called by muse, mutect2, varscan2
- PDE3A | c.2115A>C p.R705S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.036); catalogued as COSV62977108, COSV62977279; called by muse, mutect2, varscan2
- PDE4A | c.638G>A p.G213D | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.097); catalogued as COSV53358839; called by muse, mutect2
- PDE6B | c.1306G>A p.D436N | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as rs750045921, COSV55328386; called by muse, mutect2, varscan2
- PDGFRB | c.3098C>T p.A1033V | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV53838308; called by muse, mutect2, varscan2
- PDS5A | c.1798C>T p.P600S | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV57828159; called by muse, mutect2
- PDZD2 | c.3631A>C p.T1211P | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV56864541; called by muse, mutect2, varscan2
- PEG3 | c.495G>A p.W165* | Nonsense Mutation (SNP) | VAF 4/29 reads (14%) | catalogued as COSV55630584; called by muse, mutect2
- PENK | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 63/174 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as rs759815705, COSV59240234; called by muse, mutect2, varscan2
- PGS1 | c.1076C>T p.P359L | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV53146771; called by muse, mutect2, varscan2
- PHF12 | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV52020602; called by muse, mutect2, varscan2
- PHF13 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.027); catalogued as rs751441968, COSV50010550; called by muse, mutect2, varscan2
- PI4KB | c.961C>T p.R321* (on ENST00000368873 / NM_001369623.1; = p.R333* on NM_002651.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 8/116 reads (7%) | catalogued as COSV55019454; called by muse, mutect2
- PIK3C2B | c.4744G>A p.D1582N | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.909); catalogued as COSV65812939; called by muse, mutect2
- PITX2 | c.464G>A p.G155D (on ENST00000354925 / NM_001204397.1; = p.G162D on NM_000325.6) | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV60740479, COSV60741557; called by muse, mutect2, varscan2
- PKD1L1 | c.8287G>A p.E2763K | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51843306; called by muse, mutect2, varscan2
- PKDREJ | c.5015G>A p.R1672K | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs760064218, COSV53550766; called by muse, mutect2, varscan2
- PKDREJ | c.3914G>A p.R1305Q | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs760259232, COSV53549445; called by muse, mutect2, varscan2
- PKDREJ | c.1804G>A p.D602N | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.346); catalogued as rs777342821, COSV53550784; called by muse, mutect2, varscan2
- PKHD1L1 | c.10298G>A p.G3433E | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs750202549, COSV65747397; called by muse, mutect2, varscan2
- PKP3 | c.965C>T p.P322L | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV58988510; called by muse, mutect2, varscan2
- PKP4 | c.2389C>T p.P797S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as COSV61579391; called by muse, mutect2, varscan2
- PLA2G4A | c.660T>G p.C220W | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66555169; called by muse, mutect2
- PLA2G6 | c.2131C>T p.P711S | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV59271612; called by muse, mutect2, varscan2
- PLCB4 | c.2710G>A p.G904S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV53808697; called by muse, mutect2, varscan2
- PLCH1 | c.1859G>A p.G620E (on ENST00000340059 / NM_001130960.2; = p.G632E on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV58203746; called by muse, mutect2, varscan2
- PLCZ1 | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56853408; called by muse, mutect2, varscan2
- PLEC | c.9755C>T p.S3252F (on ENST00000322810 / NM_201380.4; = p.S3142F on NM_000445.5) | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1554681926, COSV59638360; called by muse, mutect2, varscan2
- PLEKHA5 | c.368A>G p.N123S | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54706005; called by muse, mutect2, varscan2
- PLEKHG2 | c.2674C>T p.P892S | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.005); catalogued as COSV52681557; called by muse, mutect2, varscan2
- PLEKHG7 | c.1078G>A p.D360N | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.029); catalogued as COSV60822232; called by muse, mutect2, varscan2
- PLXNA3 | c.1789C>T p.P597S | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63754744; called by muse, mutect2, varscan2
- PLXNA4 | c.3418C>T p.P1140S | Missense Mutation (SNP) | VAF 31/297 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267601289, COSV58142427; called by muse, mutect2, varscan2
- PMEPA1 | c.464G>C p.G155A | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV55694794; called by muse, mutect2
- POM121L12 | c.317C>T p.T106I | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV68693482, COSV68694652; called by muse, mutect2, varscan2
- POM121L12 | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1689291, COSV68692218; called by muse, mutect2, varscan2
- POR | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs374350596; called by muse, mutect2
- POU6F2 | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68877081; called by muse, mutect2
- PPP1R3F | c.1286C>T p.S429F | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs1557121376, COSV50019300; called by muse, mutect2
- PRAMEF1 | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 43/201 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs769862193, COSV60012693; called by muse, mutect2, varscan2
- PRAMEF4 | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 54/301 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs200255712, COSV52439730; called by muse, varscan2
- PRAMEF4 | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 44/238 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV52439737; called by muse, varscan2
- PRELP | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 109/225 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV58115097, COSV58116639; called by muse, mutect2, varscan2
- PRKD1 | c.1753C>T p.P585S | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.088); catalogued as COSV59575306; called by muse, mutect2, varscan2
- PRKDC | c.11077G>A p.E3693K | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV58057931; called by muse, mutect2, varscan2
- PRKG2 | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV52320331; called by muse, mutect2, varscan2
- PRMT1 | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60196535, COSV60197653; called by muse, mutect2, varscan2
- PROC | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM071940, CM123617, COSV52167068; called by muse, mutect2, varscan2
- PROKR2 | c.646C>T p.Q216* | Nonsense Mutation (SNP) | VAF 53/161 reads (33%) | catalogued as COSV54087730; called by muse, mutect2, varscan2
- PRPSAP2 | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 41/218 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV52066638; called by muse, mutect2, varscan2
- PRRC2A | c.4910C>T p.P1637L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); catalogued as COSV52992934; called by muse, mutect2, varscan2
- PRRC2B | c.4784C>T p.S1595F | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as COSV61940057; called by muse, mutect2, varscan2
- PRUNE2 | c.5935G>A p.E1979K | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.335); catalogued as rs750443357, COSV65043953; called by muse, mutect2, varscan2
- PSG9 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 61/247 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs533862888, COSV52486438, COSV52487222; called by muse, mutect2, varscan2
- PSMC6 | c.718C>T p.Q240* (on ENST00000612399; = p.Q226* on NM_002806.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 8/65 reads (12%) | catalogued as COSV71629069; called by muse, mutect2
- PTGFR | c.115G>A p.V39M | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66115816; called by muse, mutect2, varscan2
- PTK2B | c.2197C>T p.P733S | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV57760705; called by muse, mutect2, varscan2
- PTPRC | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 110/289 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.621); catalogued as COSV61415890; called by muse, mutect2, varscan2
- PTPRE | c.1193G>A p.G398E | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54554683; called by muse, mutect2, varscan2
- PVRIG | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.237); catalogued as rs764338296, COSV52781885; called by muse, mutect2, varscan2
- PWWP3B | c.266C>T p.S89L | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV61800761; called by muse, mutect2, varscan2
- PWWP3B | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.961); catalogued as rs1329842665, COSV61800589; called by muse, mutect2, varscan2
- PXDNL | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.334); catalogued as COSV100682491, COSV62484732; called by muse, mutect2
- PXDNL | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV62492962, COSV62495546; called by muse, mutect2, varscan2
- R3HDM1 | c.2971G>A p.E991K | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51522537; called by muse, mutect2, varscan2
- RAB11B | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.542); catalogued as COSV60085989; called by muse, mutect2, varscan2
- RAG2 | c.962A>G p.N321S | Missense Mutation (SNP) | VAF 53/226 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1306497047, COSV57558630; called by muse, mutect2, varscan2
- RANBP2 | c.8929C>T p.Q2977* | Nonsense Mutation (SNP) | VAF 18/77 reads (23%) | catalogued as COSV51704101; called by muse, mutect2, varscan2
- RASGRF2 | c.1520G>A p.R507K | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as COSV54133912, COSV99428740; called by muse, mutect2, varscan2
- RBBP6 | c.1813C>T p.P605S | Missense Mutation (SNP) | VAF 76/419 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.021); catalogued as COSV60506774; called by muse, mutect2, varscan2
- RECQL5 | c.415C>T p.Q139* | Nonsense Mutation (SNP) | VAF 48/334 reads (14%) | catalogued as COSV53128925; called by muse, mutect2, varscan2
- RELB | c.1247C>T p.P416L | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.63); catalogued as COSV55511625; called by muse, mutect2, varscan2
- REPS2 | c.1478C>T p.S493F | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58185103; called by muse, mutect2, varscan2
- RESF1 | c.3187C>T p.P1063S | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57023758; called by muse, mutect2, varscan2
- RESF1 | c.3745C>T p.P1249S | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.147); catalogued as rs866920961, COSV57023776; called by muse, mutect2, varscan2
- RET | c.2468G>A p.G823E | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.21); PolyPhen probably damaging (1); catalogued as rs142779213, COSV60691457; called by muse, mutect2, varscan2
- RFWD3 | c.1280C>T p.S427F | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV63098321; called by muse, mutect2, varscan2
- RFX6 | c.1573C>T p.R525* | Nonsense Mutation (SNP) | VAF 18/56 reads (32%) | catalogued as rs766695745, COSV60583298; called by muse, mutect2, varscan2
- RGL3 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 75/371 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as COSV62698476; called by muse, mutect2, varscan2
- RGS6 | c.917C>T p.S306F | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV59586409; called by muse, mutect2, varscan2
- RHOU | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV64208809; called by muse, mutect2, varscan2
- ROBO4 | c.222G>A p.M74I | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV60625826; called by muse, mutect2, varscan2
- ROS1 | c.6811G>C p.G2271R | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV63858106; called by muse, mutect2, varscan2
- RP1L1 | c.1462C>T p.Q488* | Nonsense Mutation (SNP) | VAF 25/65 reads (38%) | catalogued as rs978884122, COSV101222917, COSV66757535; called by muse, mutect2, varscan2
- RPL12 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as rs1344316695, COSV55941161; called by muse, mutect2, varscan2
- RPL3L | c.887G>A p.G296E | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51907481; called by muse, mutect2, varscan2
- RPS6KA1 | c.1070C>T p.S357F | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64810172; called by muse, mutect2, varscan2
- RRH | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV58491656; called by muse, mutect2, varscan2
- RSBN1 | c.2053C>T p.Q685* | Nonsense Mutation (SNP) | VAF 27/121 reads (22%) | catalogued as COSV54733660; called by muse, mutect2, varscan2
- RTP3 | c.23G>A p.W8* | Nonsense Mutation (SNP) | VAF 17/94 reads (18%) | catalogued as COSV56124098; called by muse, mutect2, varscan2
- RUNX1 | c.799C>T p.P267S (on ENST00000344691 / NM_001001890.3; = p.P294S on NM_001754.5) | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV55882956, COSV55887174; called by muse, mutect2, varscan2
- RYR1 | c.5158G>A p.E1720K | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.89); catalogued as rs746317037, COSV62103192; called by muse, mutect2, varscan2
- RYR3 | c.2407C>G p.P803A | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101213848, COSV66808104; called by muse, mutect2, varscan2
- RYR3 | c.2408C>T p.P803L | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101213851; called by muse, mutect2, varscan2
- RYR3 | c.3223C>T p.R1075W | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765761313, COSV66799887; called by muse, mutect2, varscan2
- S100A8 | c.68A>T p.K23M | Missense Mutation (SNP) | VAF 153/399 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.815); catalogued as COSV64198139; called by muse, mutect2, varscan2
- SAFB2 | c.1279T>G p.F427V | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53043676; called by muse, mutect2
- SALL1 | c.3677G>A p.G1226E | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.541); catalogued as rs1176615487, COSV51760854; called by muse, mutect2, varscan2
- SALL3 | c.2788G>A p.E930K | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.118); catalogued as COSV73305823; called by muse, mutect2, varscan2
- SAMD14 | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.059); catalogued as COSV53310292; called by muse, mutect2, varscan2
- SATB2 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.921); catalogued as rs1399958038, COSV53482313; called by muse, mutect2, varscan2
- SCAF1 | c.3544C>T p.P1182S | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.519); catalogued as COSV59191937; called by muse, mutect2, varscan2
- SCARB1 | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV55549911; called by muse, mutect2, varscan2
- SCN1A | c.3409G>A p.D1137N (on ENST00000303395 / NM_001202435.3; = p.D1126N on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.636); catalogued as COSV57677829; called by muse, mutect2, varscan2
- SCN5A | c.2690G>A p.G897E | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as CM159534, COSV61131745; called by muse, mutect2, varscan2
- SCN5A | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV60067697; called by muse, mutect2, varscan2
- SEC16A | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs902818908, COSV51533621; called by muse, mutect2, varscan2
- SEPTIN4 | c.755C>T p.P252L | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.005); catalogued as rs1244514548, COSV58727298; called by muse, mutect2, varscan2
- SERPINA4 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.036); catalogued as rs140397956, COSV100097396; called by muse, mutect2, varscan2
- SERPINB7 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.93); PolyPhen benign (0.018); catalogued as COSV60532670; called by muse, mutect2, varscan2
- SERPINB9 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs548120635, COSV66233422; called by muse, mutect2, varscan2
- SFMBT2 | c.1183C>T p.P395S | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV62812747; called by muse, mutect2, varscan2
- SGCA | c.602G>A p.G201D | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV56249298; called by muse, mutect2, varscan2
- SH2D5 | c.1177G>A p.E393K (on ENST00000444387 / NM_001103161.2; = p.E309K on NM_001103160.2) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs373331417; called by muse, mutect2, varscan2
- SH3YL1 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1343469328, COSV62156964; called by muse, mutect2, varscan2
- SI | c.1735C>T p.P579S | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as rs914960775, COSV52265279; called by muse, mutect2
- SIDT2 | c.1698C>A p.C566* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as COSV54058553; called by muse, mutect2, varscan2
- SIPA1L1 | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.83); PolyPhen benign (0.025); catalogued as COSV62171766; called by muse, mutect2, varscan2
- SIRPB2 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV63124512; called by muse, varscan2
- SIRPG | c.328A>C p.T110P | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53808736; called by muse, mutect2, varscan2
- SLC10A2 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs766114543, COSV55356812; called by muse, mutect2, varscan2
- SLC17A6 | c.1208T>C p.V403A | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV54138585; called by muse, mutect2, varscan2
- SLC22A2 | c.1389G>A p.R463= | Splice Region (SNP) | VAF 4/16 reads (25%) | catalogued as COSV65266572; called by muse, mutect2
- SLC22A2 | c.235G>A p.G79R | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.918); catalogued as COSV65267075; called by muse, mutect2, varscan2
- SLC25A21 | c.359G>A p.G120E | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1006470745, COSV58726498; called by muse, mutect2, varscan2
- SLC25A28 | c.770G>A p.R257K | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.96); catalogued as COSV65125546, COSV65125671; called by muse, mutect2, varscan2
- SLC25A46 | c.820C>T p.L274F | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.973); catalogued as COSV63506882; called by muse, mutect2, varscan2
- SLC26A9 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV61603396, COSV61604191; called by muse, mutect2
- SLC28A1 | c.1574G>A p.W525* | Nonsense Mutation (SNP) | VAF 32/143 reads (22%) | catalogued as rs1165176958, COSV99723407; called by muse, mutect2, varscan2
- SLC30A8 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as rs267601738, COSV69973519; called by muse, mutect2, varscan2
- SLC38A4 | c.755C>T p.P252L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.457); catalogued as COSV56969145; called by muse, mutect2, varscan2
- SLC39A4 | c.398C>T p.P133L (on ENST00000301305 / NM_001374839.1; = p.P108L on NM_017767.3) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as COSV52779951; called by muse, mutect2, varscan2
- SLC4A11 | c.22G>A p.G8R | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV101196035, COSV101196115; called by muse, mutect2, varscan2
- SLC6A1 | c.204G>A p.W68* | Nonsense Mutation (SNP) | VAF 19/93 reads (20%) | catalogued as COSV55116984; called by muse, mutect2, varscan2
- SLC7A11 | c.724G>A p.G242R | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54931498, COSV99763468; called by muse, varscan2
- SLC7A14 | c.568C>A p.L190I | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.019); catalogued as COSV51585789, COSV99200657; called by muse, mutect2, varscan2
- SLC7A3 | c.1284C>T p.L428= | Splice Region (SNP) | VAF 9/19 reads (47%) | catalogued as rs997611682, COSV53228234; called by muse, mutect2, varscan2
- SLC7A3 | c.731G>A p.G244E | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV53226750; called by muse, mutect2
- SLC7A7 | c.1499G>A p.G500E | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1195921530, COSV53537681; called by muse, mutect2, varscan2
- SLC7A7 | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53541592; called by muse, mutect2, varscan2
- SLC8A2 | c.1859G>A p.G620E | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.458); catalogued as rs1171451049, COSV52641135; called by muse, mutect2, varscan2
- SLC9C1 | c.1064T>C p.V355A | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV59890155; called by muse, mutect2
- SLC9C2 | c.1586G>A p.G529E | Missense Mutation (SNP) | VAF 28/203 reads (14%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as COSV62944519; called by muse, mutect2, varscan2
- SLCO6A1 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 62/303 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.169); catalogued as COSV65805764; called by muse, mutect2, varscan2
- SLIT2 | c.4499G>A p.R1500Q | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs766242125, COSV56564759; called by muse, mutect2, varscan2
- SLIT3 | c.4192G>A p.G1398R | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV60620464; called by muse, mutect2, varscan2
- SLITRK4 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62025069; called by muse, mutect2, varscan2
- SMG5 | c.1015G>A p.D339N | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV100700885; called by muse, mutect2, varscan2
- SMTN | c.2135C>T p.S712F | Missense Mutation (SNP) | VAF 101/196 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.157); catalogued as COSV60780423; called by muse, mutect2, varscan2
- SNAPC2 | c.335G>A p.G112E | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV55604364; called by muse, mutect2, varscan2
- SOCS5 | c.1385C>T p.P462L | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1328145841, COSV60605647; called by muse, mutect2, varscan2
- SORCS3 | c.3341C>T p.P1114L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV63816652; called by muse, mutect2, varscan2
- SORCS3 | c.3523G>A p.E1175K | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as COSV63803612; called by muse, mutect2, varscan2
- SPATA2 | c.1045C>T p.R349W | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs375848135; called by muse, mutect2, varscan2
- SPATA5L1 | c.1495A>T p.K499* | Nonsense Mutation (SNP) | VAF 10/55 reads (18%) | catalogued as COSV59745142; called by muse, mutect2, varscan2
- SPDYE5 | c.209G>A p.R70K | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.288); catalogued as COSV71596397; called by muse, mutect2, varscan2
- SPNS2 | c.1121G>A p.G374E | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61231047; called by muse, mutect2, varscan2
- SPOCK1 | c.341T>C p.L114P | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.276); catalogued as rs932859041, COSV56456156; called by muse, mutect2, varscan2
- SPPL2C | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV61292114; called by muse, mutect2, varscan2
- SPRED3 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV58313253; called by muse, mutect2
- SPRR2G | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 32/240 reads (13%) | PolyPhen possibly damaging (0.726); catalogued as rs1249608752, COSV64203016; called by muse, mutect2, varscan2
651 further variants in this file (167 protein-altering or splice-affecting, 450 silent, 34 other) are not listed here.
